Somatic mutation profile of tumor specimen ALCH-B288-TTP1-A (aliquot ALCH-B288-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B288, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,966 days).
Specimen ALCH-B288-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c114a3fe-4da5-429e-ab80-a21226f83d6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B288-NB1-A (Blood Derived Normal), aliquot ALCH-B288-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44869eeb-d2d6-4fe5-8cdf-9b24beb4f71a

The open-access MAF lists 309 somatic variants for this specimen: 210 protein-altering or splice-affecting, 60 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 60, Nonsense Mutation 16, Intron 14, RNA 11, Splice Site 8, 5'UTR 5, 5'Flank 4, Frame Shift Del 3, 3'UTR 3, Splice Region 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GARS1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 99/496 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1135401748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 65/309 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANK2 | c.11050G>T p.E3684* | Nonsense Mutation (SNP) | VAF 63/303 reads (21%) | catalogued as COSV100003350; called by muse, mutect2, varscan2
- ANKRD30B | c.1289A>T p.Q430L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs962790282; called by muse, mutect2, varscan2
- ASTL | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100668397; called by muse, mutect2
- ATF7IP | c.3094A>T p.T1032S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99662028; called by muse, mutect2, varscan2
- ATM | c.6313A>T p.R2105W | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879253983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D1 | c.1516-1G>T p.X506_splice | Splice Site (SNP) | VAF 58/418 reads (14%) | catalogued as rs1433247684; called by muse, varscan2
- CCDC96 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764906888; called by muse, mutect2, varscan2
- CD200R1L | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1559923166; called by muse, mutect2, varscan2
- CD5L | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 202/406 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV63822358, COSV63822746; called by muse, mutect2, varscan2
- CLCN2 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41266269; called by muse, mutect2, varscan2
- CNKSR2 | c.1027A>G p.R343G | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV99668140; called by muse, mutect2, varscan2
- COL11A1 | c.3115-1G>T p.X1039_splice | Splice Site (SNP) | VAF 56/261 reads (21%) | catalogued as COSV62179726; called by muse, varscan2
- COL4A5 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV60359198; called by muse, mutect2, varscan2
- CRB1 | c.1985C>A p.S662* | Nonsense Mutation (SNP) | VAF 206/443 reads (47%) | catalogued as CM153047; called by muse, mutect2, varscan2
- CSMD3 | c.8146G>T p.E2716* | Nonsense Mutation (SNP) | VAF 43/494 reads (9%) | catalogued as COSV52184375; called by muse, mutect2
- CTNNA2 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1417541064, COSV100783948, COSV63554502; called by muse, mutect2
- DNM1 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.154); catalogued as rs1181319175; called by muse, mutect2, varscan2
- DPP6 | c.1370G>A p.R457Q (on ENST00000377770 / NM_001364500.2; = p.R395Q on NM_001936.5) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs766044852, COSV59608974; called by muse, mutect2, varscan2
- EFEMP1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 24/236 reads (10%) | catalogued as rs1335365938, COSV62614755; called by muse, mutect2, varscan2
- FUT11 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); catalogued as rs747096874; called by muse, mutect2, varscan2
- GLI2 | c.2550C>A p.S850R (on ENST00000361492 / NM_001374353.1; = p.S867R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV58048840; called by muse, mutect2, varscan2
- GLT6D1 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65628549; called by muse, mutect2, varscan2
- GPR137B | c.1067T>C p.I356T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs145077949; called by muse, mutect2, varscan2
- H3-5 | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV61187172; called by muse, mutect2
- HPGD | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307537690; called by muse, mutect2
- ITSN1 | c.1478A>G p.E493G | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1569153072; called by muse, mutect2, varscan2
- KCNK15 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100865244; called by muse, mutect2, varscan2
- KCNN3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1437869897; called by muse, mutect2
- KIAA1210 | c.4367G>T p.G1456V | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs767043476, COSV68179747; called by muse, mutect2
- KIF13B | c.1774G>C p.A592P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV73054182, COSV73054682; called by muse, mutect2, varscan2
- KNTC1 | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | catalogued as rs779604603; called by muse, mutect2, varscan2
- KRTAP12-2 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs1458831789; called by muse, mutect2
- LVRN | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV63498402; called by muse, varscan2
- MAGT1 | c.241C>T p.L81F (on ENST00000618282 / NM_001367916.1; = p.L113F on NM_032121.5) | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63780738; called by muse, mutect2, varscan2
- MSH2 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51886938; called by muse, mutect2, varscan2
- MUC12 | c.896C>T p.T299M (on ENST00000379442; = p.T156M on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.551); catalogued as rs370911866; called by muse, mutect2
- MYO3A | c.1250C>A p.S417Y | Missense Mutation (SNP) | VAF 87/340 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56331631; called by muse, mutect2, varscan2
- MYO7A | c.5126C>A p.A1709D | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV101289134; called by muse, varscan2
- MYOM2 | c.3088G>T p.G1030W | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036523, COSV100037872; called by muse, mutect2, varscan2
- NCOR2 | c.2045A>G p.K682R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.319); catalogued as COSV62295511; called by muse, mutect2, varscan2
- NEK5 | c.1982C>A p.A661E | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs138340585, COSV62882218; called by muse, mutect2, varscan2
- NF1 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs587782772, COSV62195017; ClinVar: uncertain significance; called by muse, mutect2
- NIPAL1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 37/357 reads (10%) | catalogued as COSV55007153; called by muse, mutect2, varscan2
- NLRP13 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.728); catalogued as rs1223495285, COSV61623345; called by muse, varscan2
- NUGGC | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs751612628, COSV58435910, COSV58439665; called by muse, mutect2, varscan2
- OBSCN | c.6767C>G p.T2256S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs1281123187; called by muse, mutect2, varscan2
- PCDHB12 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53399546; called by muse, mutect2, varscan2
- PCDHGB4 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759399243; called by muse, mutect2, varscan2
- PGK1 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 63/307 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs782518190; called by muse, mutect2, varscan2
- PGLYRP2 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs747605834; called by muse, mutect2, varscan2
- PICALM | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 97/382 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as rs779406084, COSV62669178; called by muse, mutect2, varscan2
- PLCD1 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765870286, COSV52188969; called by muse, mutect2, varscan2
- PRUNE2 | c.6200C>T p.A2067V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs374932024, COSV104428525; called by muse, mutect2, varscan2
- PTPRD | c.3169G>C p.G1057R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.276); catalogued as COSV61933394; called by muse, mutect2, varscan2
- RAB9B | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV54587995; called by muse, mutect2
- RELN | c.9751G>A p.E3251K | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as rs376520049; ClinVar: uncertain significance; called by muse, mutect2
- REV1 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1559284526; called by muse, mutect2, varscan2
- RFC4 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56216870; called by muse, mutect2
- RNMT | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51084276, COSV51091802; called by muse, mutect2, varscan2
- RYR2 | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63664217; called by muse, mutect2, varscan2
- SALL1 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51755268, COSV51757236; called by muse, mutect2, varscan2
- SCN2A | c.3133C>G p.L1045V | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.34); catalogued as rs369128399; called by muse, mutect2, varscan2
- SERPINB4 | c.1031C>A p.A344E | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1291155227; called by muse, mutect2
- SINHCAF | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1462165740, COSV61797140; called by muse, mutect2, varscan2
- SLC9A3 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53799351; called by muse, mutect2, varscan2
- SLITRK4 | c.1654G>T p.G552W | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs145611405; called by muse, varscan2
- STAB2 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66340602; called by muse, mutect2, varscan2
- STK32A | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 24/249 reads (10%) | catalogued as rs749568069, COSV60414500; called by muse, mutect2
- TMC2 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62658056; called by muse, mutect2
- TNS4 | c.1174C>A p.P392T | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV54184475; called by muse, mutect2, varscan2
- TRIM42 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs974729556; called by muse, mutect2, varscan2
- VNN2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1204346828; called by muse, mutect2, varscan2
- VRTN | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs367558909; called by muse, mutect2, varscan2
- ZFHX3 | c.10139A>T p.Q3380L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV51713307; called by muse, mutect2, varscan2
- ZFP92 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1556975134; called by muse, varscan2
- ZMYM3 | c.4018G>T p.D1340Y | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58740864; called by muse, mutect2, varscan2
- ZNF18 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV59552647; called by muse, mutect2
- ZNF320 | c.1296G>T p.R432S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV67087750; called by muse, mutect2, varscan2
- ZNF681 | c.131-1G>T p.X44_splice | Splice Site (SNP) | VAF 38/176 reads (22%) | catalogued as COSV68073467; called by muse, mutect2, varscan2
- ZNF711 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52157927, COSV52160359; called by muse, mutect2, varscan2
- ADGRA1 | c.1330C>A p.L444M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ANK2 | c.822del p.R276Efs*7 | Frame Shift Del (DEL) | VAF 70/385 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD36C | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANO6 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 31/323 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); called by muse, mutect2
- ASPM | c.6477G>T p.Q2159H | Missense Mutation (SNP) | VAF 231/499 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATP13A1 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2B1 | c.1111G>T p.V371F | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BHLHE23 | c.17C>A p.S6* (on ENST00000370346; = p.S22* on NM_080606.4) | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- BHLHE41 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFC | c.1140del p.M381Wfs*24 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- C7orf26 | c.992G>A p.R331K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- CCDC168 | c.15626C>A p.S5209Y | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CDH10 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CENPE | c.5117A>C p.K1706T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- CNTNAP5 | c.3653-1G>A p.X1218_splice | Splice Site (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- CREB3L2 | c.1472A>T p.E491V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP4F12 | c.596C>A p.T199N | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DCAF12L1 | c.1015C>G p.Q339E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DHX8 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIP2A | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- DNAH9 | c.1816A>G p.T606A | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSEL | c.3105G>T p.R1035S | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ECI1 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHX3 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPYC | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 59/293 reads (20%) | called by muse, mutect2, varscan2
- EXOSC10 | c.1972A>T p.I658F | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- FAM47C | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- FARS2 | c.558G>C p.Q186H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT1 | c.7876G>T p.G2626C | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD3 | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FHL1 | c.122T>A p.V41E | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- FLG | c.11477C>G p.S3826* | Nonsense Mutation (SNP) | VAF 22/428 reads (5%) | called by muse, mutect2
- FMN2 | c.2444C>A p.S815Y | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- GEMIN4 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.496); called by muse, mutect2
- GNPTAB | c.1613-1G>A p.X538_splice | Splice Site (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- GOLGA3 | c.1694A>T p.Q565L | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- GOLGA6A | c.866C>A p.A289E | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GPC6 | c.716G>C p.S239T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GRIK5 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); called by muse, mutect2
- H3C4 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2
- HCN1 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- HMGXB3 | c.2675G>T p.G892V (on ENST00000613459; = p.G646V on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- IDH3G | c.1146C>G p.H382Q | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL27RA | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ING1 | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.029); called by muse, mutect2
- INO80B | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- IQSEC2 | c.2263C>T p.R755W (on ENST00000642864 / NM_001111125.3; = p.R550W on NM_015075.2) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ITGA6 | c.3124C>T p.P1042S (on ENST00000442250; = p.P1003S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KCP | c.3697C>A p.P1233T (on ENST00000620378; = p.P1357T on NM_001366122.1) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHDRBS2 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLHL22 | c.1719G>T p.W573C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK14 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KRT1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 63/461 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMA2 | c.4760C>T p.A1587V | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- LAPTM4B | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LRIT2 | c.137T>A p.L46* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- LRP1B | c.2381-2A>T p.X794_splice | Splice Site (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2
- LRRC72 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- LRRD1 | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); called by muse, varscan2
- LYPLA1 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- MAD1L1 | c.1541G>T p.R514L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MAP3K4 | c.3958C>G p.Q1320E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MINDY2 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MINDY4 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MN1 | c.3481C>T p.Q1161* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- MUC16 | c.4556A>T p.Q1519L | Missense Mutation (SNP) | VAF 47/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- MUC17 | c.9530T>A p.V3177D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- MUC17 | c.11375G>A p.S3792N | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MYO1G | c.2312A>G p.D771G | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.1888C>A p.R630S | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2
- NEFM | c.1624G>T p.G542* | Nonsense Mutation (SNP) | VAF 36/387 reads (9%) | called by muse, mutect2
- NELFCD | c.1081C>T p.H361Y (on ENST00000602795; = p.H343Y on NM_198976.4) | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2
- NEXMIF | c.2527G>T p.G843C | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- NLRC4 | c.2520A>T p.L840= | Splice Region (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- NOX1 | c.692C>A p.T231K | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- OBSL1 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, varscan2
- OR14A2 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, varscan2
- OR14A2 | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR4C13 | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- OR51T1 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDH15 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PCDHA13 | c.2338C>A p.L780M | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHB15 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB7 | c.2053C>G p.Q685E | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PDZRN4 | c.2510C>A p.S837* (on ENST00000402685 / NM_001164595.2; = p.S579* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- PFKFB1 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNB3 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PRRC2C | c.868G>A p.A290T (on ENST00000367742; = p.A288T on NM_015172.4) | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, varscan2
- PSMB4 | c.782+3G>C | Splice Region (SNP) | VAF 124/256 reads (48%) | called by muse, mutect2, varscan2
- RBM19 | c.378+1G>A p.X126_splice | Splice Site (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- RCOR1 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.06); called by mutect2, varscan2
- RNF139 | c.189T>A p.F63L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNMT | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAG | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, varscan2
- SERPINA4 | c.1120G>A p.G374S | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- SETD1B | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SH3TC1 | c.3218G>T p.W1073L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- SHISA9 | c.1121_1122insG p.N374Kfs*82 | Frame Shift Ins (INS) | VAF 18/136 reads (13%) | called by mutect2, pindel*, varscan2
- SLC15A3 | c.610T>A p.W204R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC23A2 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- SLC29A1 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.033); called by muse, mutect2
- SLC39A10 | c.221A>T p.N74I | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SLC39A4 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SNAP91 | c.2045C>A p.P682Q | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SPINK2 | c.236T>G p.I79S | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SPOP | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2
- SSX5 | c.240G>T p.Q80H (on ENST00000347757 / NM_175723.1; = p.Q121H on NM_021015.4) | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, varscan2
- STAB2 | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SUMF2 | c.403C>T p.L135F (on ENST00000652303; = p.L116F on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13C | c.2756G>C p.G919A | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.942); called by muse, mutect2
- TLR6 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TMOD2 | c.968del p.K323Sfs*33 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | called by mutect2, pindel*, varscan2
- TNFSF11 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 83/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPC5 | c.2724A>C p.E908D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.031); called by muse, mutect2
- TTLL10 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.99625T>A p.L33209I (on ENST00000591111; = p.L25785I on NM_003319.4) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | PolyPhen benign (0.249); called by muse, mutect2, varscan2
- USP29 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2
- VAMP7 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VDR | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- VN1R5 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWDE | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WASHC5 | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 27/522 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- WDR13 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF211 | c.1460G>A p.S487N (on ENST00000347302 / NM_198855.4; = p.S500N on NM_006385.5) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZNF320 | c.1295G>T p.R432M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF460 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF787 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSCAN12 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ABCA3 | c.4221G>A p.Q1407= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV57055935; called by muse, mutect2, varscan2
- ADAMTS7 | c.153C>A p.V51= | Silent (SNP) | VAF 88/277 reads (32%) | catalogued as COSV66306901; called by muse, varscan2
- AKAP9 | c.5316G>A p.K1772= (on ENST00000359028; = p.K1740= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/391 reads (20%) | called by muse, mutect2, varscan2
- AMMECR1 | c.849G>C p.P283= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as COSV99466698; called by muse, mutect2, varscan2
- ASIP | c.306G>A p.P102= | Silent (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- BAG1 | c.384G>T p.S128= | Silent (SNP) | VAF 17/150 reads (11%) | called by muse, varscan2
- BEND7 | c.471T>G p.T157= | Silent (SNP) | VAF 75/245 reads (31%) | called by muse, mutect2, varscan2
- CCDC22 | c.1342C>A p.R448= | Silent (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- CD163 | c.3138C>T p.S1046= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs1447957637; called by muse, mutect2, varscan2
- CEP97 | c.2409T>C p.A803= | Silent (SNP) | VAF 51/223 reads (23%) | catalogued as rs1156891880; called by muse, mutect2, varscan2
- COL24A1 | c.2691G>T p.G897= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs762851721; called by muse, mutect2, varscan2
- COL4A6 | c.151C>A p.R51= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV57878447; called by muse, mutect2
- COL5A1 | c.1428C>T p.P476= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs745633063, COSV100880353; called by muse, mutect2
- COL6A6 | c.3570G>A p.V1190= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- CWH43 | c.849T>A p.A283= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- DAPK1 | c.3744C>A p.P1248= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV63786701; called by mutect2, varscan2
- EDA2R | c.81A>T p.L27= | Silent (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- FAM78B | c.381C>T p.P127= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs1322193464; called by muse, mutect2, varscan2
- FLVCR2 | c.912C>G p.L304= | Silent (SNP) | VAF 38/389 reads (10%) | called by muse, varscan2
- FRMPD3 | c.1650G>T p.T550= | Silent (SNP) | VAF 25/192 reads (13%) | called by muse, mutect2, varscan2
- GABBR1 | c.819C>A p.A273= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- GBP5 | c.1503G>A p.A501= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs1483909139, COSV58593727; called by muse, mutect2, varscan2
- GYPB | c.126A>T p.S42= | Silent (SNP) | VAF 70/367 reads (19%) | called by muse, mutect2, varscan2
- GZMM | c.564C>G p.P188= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- HCFC2 | c.822A>G p.S274= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as COSV57560470; called by muse, mutect2, varscan2
- HSPB11 | c.351C>T p.F117= | Silent (SNP) | VAF 47/190 reads (25%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.132T>C p.S44= | Silent (SNP) | VAF 16/255 reads (6%) | called by muse, mutect2
- IQSEC2 | c.3457C>A p.R1153= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- KNL1 | c.6441C>T p.F2147= (on ENST00000346991 / NM_170589.5; = p.F2121= on NM_144508.5) | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs1337952854; called by muse, mutect2, varscan2
- LAMC2 | c.993G>T p.L331= | Silent (SNP) | VAF 192/423 reads (45%) | catalogued as COSV51459156; called by muse, mutect2, varscan2
- MACF1 | c.17781C>T p.C5927= (on ENST00000372915; = p.C3972= on NM_012090.5) | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- MRPL15 | c.138T>C p.G46= | Silent (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- MXRA5 | c.4459C>A p.R1487= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV54252789; called by muse, mutect2, varscan2
- NBPF11 | c.2121G>A p.L707= | Silent (SNP) | VAF 9/30 reads (30%) | called by mutect2, varscan2
- NOCT | c.429C>T p.I143= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1322601884; called by muse, mutect2, varscan2
- NR2C1 | c.255C>T p.T85= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as rs528296618; called by muse, mutect2
- OR10H2 | c.639C>T p.L213= | Silent (SNP) | VAF 13/187 reads (7%) | catalogued as rs866737894, COSV59945819; called by muse, mutect2
- OR2T12 | c.606G>A p.V202= | Silent (SNP) | VAF 22/508 reads (4%) | catalogued as COSV100527934; called by muse, mutect2
- PCDHGB3 | c.1476G>T p.V492= | Silent (SNP) | VAF 57/211 reads (27%) | called by muse, mutect2, varscan2
- PGM1 | c.1344G>C p.L448= | Silent (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- PPIAL4A | c.54C>A p.G18= | Silent (SNP) | VAF 86/231 reads (37%) | catalogued as rs1230116445; called by muse, mutect2, varscan2
- PRR33 | c.462A>G p.V154= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- PRR5-ARHGAP8 | c.756G>T p.V252= (on ENST00000352766; = p.V129= on NM_181334.5) | Silent (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- RASL10B | c.306C>T p.Y102= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs146982096; called by mutect2, varscan2
- RBMXL3 | c.3063G>A p.P1021= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs375818310, COSV57745079; called by muse, mutect2
- RDH12 | c.675C>A p.T225= | Silent (SNP) | VAF 70/371 reads (19%) | called by muse, mutect2, varscan2
- RP1 | c.1935A>T p.L645= | Silent (SNP) | VAF 127/406 reads (31%) | called by muse, mutect2, varscan2
- SAGE1 | c.2181G>A p.E727= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV61019704; called by muse, mutect2
- SBK3 | c.828G>A p.A276= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs111546672; called by muse, mutect2
- SLC9A3 | c.726G>T p.V242= | Silent (SNP) | VAF 38/285 reads (13%) | called by muse, mutect2, varscan2
- STRIP2 | c.348A>T p.L116= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV99973578; called by muse, mutect2
- TBC1D1 | c.1174C>T p.L392= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs1259287760; called by muse, mutect2, varscan2
- TMEM130 | c.912C>A p.T304= | Silent (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- TRIM31 | c.264C>G p.S88= | Silent (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- TRIM32 | c.549A>G p.A183= | Silent (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.201A>G p.Q67= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs376577358; called by mutect2, varscan2
- USP36 | c.1479C>G p.G493= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV61755032; called by muse, mutect2, varscan2
- YBX1 | c.813C>A p.T271= | Silent (SNP) | VAF 32/268 reads (12%) | called by muse, varscan2
- ZAP70 | c.1422C>T p.Y474= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs202012936, COSV99070249; called by muse, mutect2, varscan2
- ZFX | c.1632G>A p.K544= | Silent (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- AC093802.1 | n.82G>T | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+486G>A | Intron (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1567G>T | RNA (SNP) | VAF 14/127 reads (11%) | called by muse, varscan2
- AC136759.1 | n.1439G>A | RNA (SNP) | VAF 45/399 reads (11%) | catalogued as rs775423664; called by muse, mutect2, varscan2
- ANKRD26P1 | n.677A>G | RNA (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505401 T>A | 5'Flank (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2
- AP001007.2 | n.142C>A | RNA (SNP) | VAF 65/265 reads (25%) | called by muse, mutect2, varscan2
- CDH9 | c.999+78C>T | Intron (SNP) | VAF 66/320 reads (21%) | called by muse, mutect2, varscan2
- COL11A1 | c.5041-32C>A | Intron (SNP) | VAF 19/78 reads (24%) | catalogued as rs753455106; called by muse, mutect2, varscan2
- DISC1 | c.1793-50G>T | Intron (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+641C>A | Intron (SNP) | VAF 64/263 reads (24%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.6618+26C>T | Intron (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010372 C>G | 5'Flank (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- FMR1 | c.*331T>G | 3'UTR (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- FRG2KP | chr16:31569146 G>T | 5'Flank (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- GALNT13 | c.312-5942A>T | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2
- GNRHR | c.-11C>A | 5'UTR (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- GUSBP1 | n.180-4576A>T | Intron (SNP) | VAF 38/1094 reads (3%) | called by muse, mutect2
- HIRA | c.*230C>T | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs781983881; called by muse, mutect2, varscan2
- IGKV2D-29 | c.-21T>A | 5'UTR (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- ISCA1P1 | n.226G>A | RNA (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- LILRB1 | chr19:54638705 T>A | 3'Flank (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- LINC00583 | n.240A>T | RNA (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- LINC02876 | n.236C>G | RNA (SNP) | VAF 49/325 reads (15%) | called by muse, mutect2, varscan2
- LINGO3 | c.-67C>A | 5'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- MYH16 | n.3314del | RNA (DEL) | VAF 22/160 reads (14%) | called by pindel, varscan2
- NAA60 | c.*206+28G>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- NDUFAF5 | c.*781A>T | 3'UTR (SNP) | VAF 63/418 reads (15%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1040C>G | RNA (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2312G>T | RNA (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- NUCB1 | c.758-32C>T | Intron (SNP) | VAF 17/106 reads (16%) | catalogued as rs1555792144; called by muse, mutect2
- PTGES2 | chr9:128128349 C>A | 5'Flank (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- SARDH | c.915+4305G>C | Intron (SNP) | VAF 4/46 reads (9%) | called by mutect2, varscan2
- SEPTIN3 | c.-43G>T | 5'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- SLC25A48 | c.-6C>A | 5'UTR (SNP) | VAF 34/75 reads (45%) | catalogued as rs753275925; called by muse, mutect2, varscan2
- SLC7A13 | c.1180-924G>A | Intron (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- TMEM67 | chr8:93819096 C>G | 3'Flank (SNP) | VAF 34/270 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.10303+1389C>T | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, varscan2
- UGT2A1 | c.715+11123G>C | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
